Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2QC, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2QC-01A (Primary Tumor).

[page 1 of 2]
ICHA Discrepancy		☒

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

year old female with left thyroid nodule consistent with PTCA.

Specimens Submitted:

1: Left thyroid lobe and part of right thyroid lobe, partial thyroidectomy

DIAGNOSIS:

1. Left thyroid lobe and part of right thyroid lobe, partial thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.3 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

Identified

Type: Follicular type

1CB-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

8/31/11

[page 2 of 2]
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "left thyroid lobe and part of right thyroid lobe" and consists of a thyroid weighing 14.0 g. The left lobe measures 2.9 x 2.7 x 2.1 cm, the fragment of right lobe measures 1.5 x 0.5 x 0.4 cm and the isthmus measures 0.6 x 0.4 x 0.4 cm. A 3.0 x 2.0 x 0.7 minute fragment of skeletal muscle is attached to the lower pole of the left lobe. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 2.3 x 2.1 x 2.0 cm unencapsulated tan white nodule with a finely granular cut surface epicentered in the left upper pole and a second nodule with a similar cut surface and measuring 1.4 x 1.4 x 1.2 cm epicentered in the left lower pole. There is a 0.8 x 0.6 x 0.5 cm tan white fleshy nodule in the fragment of right thyroid lobe. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the 2.3 cm nodule is submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N1 - 2.3 cm nodule
N2 - 1.4 cm nodule
RL - right lobe including the 0.8 cm nodule
IS - isthmus
SM - skeletal muscle at the lower pole of left lobe

Summary of Sections:

Part 1: Left thyroid lobe and part of right thyroid lobe, partial thyroidectomy

Block	Sect. Site	PCs
1	l	1
6	n1	6
1	n2	1
1	rl	1
2	sm	2

Source: NCI Genomic Data Commons file 81ac8288-79c8-46b2-bd70-8b7c0a70bfe2 (TCGA-DJ-A2QC.56AEDDE4-62FD-4D06-BA3A-018ABA76D383.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).